Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EQ, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EQ-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Melanoma, epithelioid & spindle cell mixed 8770/3

Date ^{USCF} Choroid C69.3

^{path} Uveal tract C69.4

JWS 2/16/14

Enucleation of the right eye

Macroscopy

The eyeball measures 25 mm with a segment of optic nerve of 5 mm.

At the section, a tumor nodule measuring 20X13 mm is observed.

See attached path discrepancy form for epithelioid and spindle cell ratio.

Microscopy

The tumor observed macroscopically presents the microscopic appearance of an uveal melanoma. This tumor is composed of epithelioid (80%) and of fusiform cells (20%). The cells present a large nucleolus. Presence of mitotic features.

The tumor measures 20 mm main line et 13 mm in thickness. It is developed close to the ciliary body which is partially invaded. The iris and the anterior chamber are free of tumor. The tumor is at distance from the optic nerve which is free on its entire course. There is a tumor extension on the inner half part of the sclera, without extra-scleral exteriorisation.

Conclusion

Uveal melanoma composed of epithelioid and of fusiform cells.

Tumor size: 20 mm main line.

Focal infiltration of the ciliary body

Tumor infiltration of the inner half part of the sclera, without extra-scleral extension.

Optic nerve on its entire course, optic nerve cut end and meningeal sheaths free of tumor.

ICD-O Discrepancy		☒

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	80% epithelioid cells 20% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the Initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file d29a439a-618f-4e8b-bd11-3f50b7e39115 (TCGA-V4-A9EQ.141E5856-DC2C-4684-BC4E-509E43B3914E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).